Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAHR, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-2G-AAHR-01A (Primary Tumor).

Department of Pathology

Direct dial

Mobile:

Internal postal address

E-mail

Date

Concerning

Postal address

Street address

Summary pathology report

Right orchidectomy; seminoma; diameter 5.0 cm; no angio-invasion; no invasion of rete testis;
no invasion of tunica albuginea; epididymis and spermatic cord not present in the available
slides.

Date of procurement (= date of orchidectomy):

ICD O-3

Seminoma NOS 9061/3

Site @ Testis NOS 662.9

W 3/7/14

pathologist

professor of pathology

Criteria	W 1/18/14	Yes	No

Source: NCI Genomic Data Commons file 6e43946f-f8c2-45d9-84cc-6f1f7cca2b65 (TCGA-2G-AAHR-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).